Gene-level copy-number profile of tumor specimen TCGA-63-A5ML-01A from TCGA case TCGA-63-A5ML, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5ML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.92c84d78-7402-4e20-90e8-7f4615136ce7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5ML-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af38eea9-4758-4f97-9bbe-95729d25009c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2,215; copy number 2: 32,665; copy number 3: 16,886; copy number 4: 5,716; copy number 5: 443; copy number 8: 1,276; copy number 9: 524; copy number 10: 21; copy number 13: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5ML-01A-31D-A27J-01): tumor purity 0.71, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–331,026, 12 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,323 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 8–9 (broad region; genes not listed).
- chr8:2,726,956–2,926,689, 3 genes, copy number 5 (within-gene range 3–5): AC246817.1, AC115485.1, AC023296.1.
- chr11:35,860,249–41,459,773, 37 genes, copy number 5 (within-gene range 3–5): KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1.
- chr11:91,382,909–91,383,289, 1 gene, copy number 5: AP002791.1.
- chr14:31,014,646–32,018,685, 25 genes, copy number 5–10: MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1.
- chr19:27,638,483–39,943,680, 457 genes, copy number 5–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
